Surgical pathology report (de-identified scan), TCGA case TCGA-XV-A9VZ, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  Capital Biosciences, specimen TCGA-XV-A9VZ-01A (Primary Tumor).

Pathology Report

Date:

Patient ID:

Age:

Sex:

F

Clinical Dx:

Melanoma

Tumor Location:

Skin

Localization:

Left femur

Source:

Epithelial melanoma

Clark Level (1-5):

4

Breslow (mm):

5

Tumor:

4

Normal:

0

Metastasis:

0

Stage (I-IV):

II

Tumor size (mm x mm):

4x5

NeoAdj ImmunoTx:

No

ICD-O-3

Melanoma NOS 8724/3
Site, @ Leg NOS C44.7
QW 3/12/14

Source: NCI Genomic Data Commons file de83b6a2-8f9d-42ce-be72-f8230b369894 (TCGA-XV-A9VZ.E7F88623-7C02-432C-BA63-F141937F22A5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).